Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A8WG, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A8WG-01A (Primary Tumor).

[page 1 of 2]
ICD6.3
Adenocarcinoma NOS S140/3
Site Esophagus, distal third
015.5
N03114

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) STOMACH, "POLYP" AT HIATAL HERNIA, BIOPSY:

Oxyntic/fundic mucosa with chronic inactive gastritis and muscularis mucosae hyperplasia.
No tumor, intestinal metaplasia or *Helicobacter pylori* identified.
Deeper levels are examined.

(B) ESOPHAGUS, DISTAL, TUMOR, BIOPSY:

ULCERATED INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA UNDERLYING SQUAMOUS MUCOSA
WITH REACTIVE EPITHELIAL CHANGES.

COMMENT

Immunohistochemistry performed and reviewed at

shows the neoplastic cells are negative for chromogranin and

synaptophysin.

GROSS DESCRIPTION

(A) POLYP AT HIATAL HERNIA - Multiple light gray and pink fragments of soft tissue (0.7 x 0.3 x 0.3 cm in aggregate). Entirely submitted in A1.

(B) DISTAL ESOPHAGEAL TUMOR - Multiple light gray and pink fragments of soft tissue (1.0 x 0.4 x 0.3 cm in aggregate). Entirely submitted in B1.

BIOMARKER TESTING

PRIMARY TUMOR: Block B1

NORMAL: Block A1

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

. These tests have not been

Start of ADDENDUM

[page 2 of 2]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to report special studies/IHC/Molecular studies.

Addendum completed by

COMMENT

An immunohistochemical stain for Her2-neu was performed in our lab on a representative formalin-fixed paraffin-embedded section of distal esophageal adenocarcinoma, Block: B1.

Staining	Score	Interpretation
No membranous staining of the invasive tumor cells	0	Negative

FOOTNOTE:

For Her 2: Positive cases are defined as those with strong complete, basolateral, or lateral membranous reactivity in $\geq 10\%$ of invasive tumor cells in resection specimen or strong complete, basolateral, or lateral membranous reactivity in any invasive tumor cells in biopsy specimen (Score 3+). Negative cases are defined as those with no staining (Score 0) or faint or barely perceptible membranous staining (Score 1+) of the invasive tumor cells. Equivocal cases are defined as those with weak to moderate complete, basolateral or lateral membranous reactivity in $\geq 10\%$ of invasive tumor cells in resection specimen or weak to moderate complete, basolateral or lateral membranous reactivity in any invasive tumor cells in biopsy specimen (Score 2+).

Reference Hofmann M, Stoss O, Shi D et al. Assessment of a HER2 scoring system for gastric cancer: results from a validation Study. Histopathology. 2008;52(7):797-805.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	hw 12/2/13	Yes	No

Source: NCI Genomic Data Commons file 86cff136-0fff-4153-90d3-c5d95ad202f3 (TCGA-R6-A8WG.CAD1CB99-68A3-4BB4-8584-17866244FDE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).